CCDI case PBCAGD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a3c7f117-9bb1-49df-b1c3-cdb95cd1d19a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,257 days).

Biospecimens (3 samples)
- Sample 0DMBLI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBM2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBMA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
